Somatic mutation profile of tumor specimen ALCH-B1YU-TTP1-A (aliquot ALCH-B1YU-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1YU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.4 years (25,336 days).
Specimen ALCH-B1YU-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec3f5026-945a-46d9-ad8d-40da6247397a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1YU-NB1-A (Blood Derived Normal), aliquot ALCH-B1YU-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e499c6a7-1147-403e-8281-7fb2d815de43

The open-access MAF lists 49 somatic variants for this specimen: 36 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 6, Nonsense Mutation 4, RNA 3, Intron 3, Splice Region 2, Splice Site 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM5 | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 28/630 reads (4%) | catalogued as rs753842704; called by muse, mutect2
- BPI | c.225G>T p.K75N (on ENST00000262865; = p.K71N on NM_001725.3) | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV99480299; called by muse, mutect2
- COL4A4 | c.930G>T p.R310= | Splice Region (SNP) | VAF 12/372 reads (3%) | catalogued as COSV100306041; called by muse, mutect2
- DRD5 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.188); catalogued as COSV58580844; called by muse, mutect2
- DST | c.1790A>C p.N597T (on ENST00000361203 / NM_001374722.1; = p.N271T on NM_001723.6) | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV54996005; called by muse, mutect2
- HECW1 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs770604403, COSV67828386; called by muse, mutect2
- HMCN1 | c.3314G>C p.S1105T | Missense Mutation (SNP) | VAF 25/675 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.383); catalogued as COSV54925825; called by muse, mutect2
- LRP1 | c.2743G>A p.D915N | Missense Mutation (SNP) | VAF 12/307 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1376568826; called by muse, mutect2
- LUZP4 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 10/218 reads (5%) | catalogued as rs782503093, CM134624, COSV64218880; called by muse, mutect2
- MDN1 | c.6778G>C p.E2260Q | Missense Mutation (SNP) | VAF 13/376 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65517048, COSV65521672; called by muse, mutect2
- MYO1D | c.2750T>C p.V917A | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.875); catalogued as rs1292653470; called by muse, mutect2
- RPN2 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1216823175; called by muse, mutect2, varscan2
- SORBS2 | c.1101C>G p.I367M | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV53019787; called by muse, mutect2
- TP53 | c.150del p.I50Mfs*73 | Frame Shift Del (DEL) | VAF 13/133 reads (10%) | catalogued as CM077985; called by mutect2, pindel, varscan2
- TULP1 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 33/437 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs754221623, COSV57692098; called by muse, mutect2
- ABI2 | c.1327G>C p.E443Q (on ENST00000295851 / NM_001375719.1; = p.E405Q on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/209 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); called by muse, mutect2
- BIVM-ERCC5 | c.3358C>T p.L1120F | Missense Mutation (SNP) | VAF 17/464 reads (4%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.189); called by muse, mutect2
- ESPL1 | c.2085+2T>C p.X695_splice | Splice Site (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- FZD3 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GLUL | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 17/513 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRP1 | c.3280G>C p.E1094Q | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MACF1 | c.12826G>C p.D4276H (on ENST00000372915; = p.D2209H on NM_012090.5) | Missense Mutation (SNP) | VAF 16/244 reads (7%) | called by muse, mutect2
- MRFAP1L1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 13/282 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.06); called by muse, mutect2
- NLGN4X | c.928G>T p.D310Y | Missense Mutation (SNP) | VAF 19/292 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDZD8 | c.2216T>C p.V739A | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2
- RCAN2 | c.30G>A p.M10I | Missense Mutation (SNP) | VAF 8/201 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.584); called by muse, mutect2
- RPL10 | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SGSH | c.664-4C>T | Splice Region (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- SHANK2 | c.4325A>G p.K1442R | Missense Mutation (SNP) | VAF 30/557 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.011); called by muse, mutect2
- SHROOM4 | c.4276G>T p.E1426* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- SWAP70 | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 38/560 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.388); called by muse, mutect2
- THUMPD2 | c.98A>T p.E33V | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); called by muse, mutect2
- TTN | c.48107C>G p.S16036C (on ENST00000591111; = p.S8612C on NM_003319.4) | Missense Mutation (SNP) | VAF 21/718 reads (3%) | PolyPhen probably damaging (0.98); called by muse, mutect2
- USP9X | c.6728C>G p.S2243* | Nonsense Mutation (SNP) | VAF 24/412 reads (6%) | called by muse, mutect2
- VPS13D | c.8854G>C p.E2952Q | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.63); called by muse, mutect2
- ZNF711 | c.1457C>A p.A486E | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- MCF2L2 | c.3288G>C p.A1096= | Silent (SNP) | VAF 12/145 reads (8%) | catalogued as rs1259847396; called by muse, mutect2
- PDE6B | c.1506C>T p.Y502= | Silent (SNP) | VAF 18/266 reads (7%) | catalogued as rs750323428, COSV55328596; ClinVar: benign / uncertain significance; called by muse, mutect2
- PLPPR3 | c.66C>T p.Y22= | Silent (SNP) | VAF 5/84 reads (6%) | catalogued as rs749828110; called by muse, mutect2
- RAG1 | c.2406C>A p.G802= | Silent (SNP) | VAF 14/496 reads (3%) | called by muse, mutect2
- SIGLEC7 | c.900C>T p.P300= | Silent (SNP) | VAF 15/272 reads (6%) | called by muse, mutect2
- SPANXN3 | c.39G>A p.T13= | Silent (SNP) | VAF 11/186 reads (6%) | catalogued as rs148202641, COSV65140089; called by muse, mutect2
- AC136628.2 | n.801C>T | RNA (SNP) | VAF 15/234 reads (6%) | catalogued as rs1003092982; called by muse, mutect2
- CTTN | c.902-393C>G | Intron (SNP) | VAF 14/386 reads (4%) | called by muse, mutect2
- HSPA12A | c.41-20G>A | Intron (SNP) | VAF 24/352 reads (7%) | catalogued as rs371603810; called by muse, mutect2
- MIR193B | n.34G>A | RNA (SNP) | VAF 8/189 reads (4%) | called by muse, mutect2
- OR4C4P | n.612G>A | RNA (SNP) | VAF 16/253 reads (6%) | catalogued as rs1465434019; called by muse, mutect2
- TTBK2 | c.823-6423C>T | Intron (SNP) | VAF 18/326 reads (6%) | catalogued as rs183043570; called by muse, mutect2
- ZNF20 | c.-112G>T | 5'UTR (SNP) | VAF 15/336 reads (4%) | called by muse, mutect2
